Surgical pathology report (de-identified scan), TCGA case TCGA-18-3415, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-3415-01A (Primary Tumor).

[page 1 of 6]
Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Pleura: biopsy chest wall margin - QS on silk stitch
2. Lymph node: paraesophageal node
3. Lymph node: inf. pulm ligament ST9
Lymph node: Interlobar ST11
4. Other: chest wall margin #2 tumour QS
6. Lymph node: Rt. TB angle ST10R
7. LUNGS: Rt. upper lobe QS bronchial margin
8. LUNGS: final bronchial margin
9. Lymph node: Rt. up paratracheal ST2R
10. Lymph node: Rt. low paratracheal ST4R
11. Lymph node: Subcarinal ST7

DIAGNOSIS

1. Soft tissue, biopsy (chest wall margin):
- Fibroadipose tissue and lymph node, negative for malignancy
- 2-4. Lymph nodes, biopsies (paraesophageal node, ST9 inferior pulmonary ligament, ST11 interlobar):
- Lymph nodes, negative for malignancy (x3)
5. Soft tissue, biopsy (chest wall margin #2):
- Fibroadipose tissue, negative for malignancy
6. Lymph node, biopsy (ST10R right TB angle):
- Lymph node, negative for malignancy
7. Lung, resection (right upper lobe):
a) Invasive poorly differentiated squamous cell carcinoma, with (see comment):
i) Greatest dimension = 6.6 cm
ii) Focal invasion of visceral pleura

[page 3 of 6]
COMMENT

7. Sections of the tumor show a poorly differentiated squamous cell carcinoma that focally invades through the visceral pleura. There is associated with the tumor an area of pulmonary infarction and fibrosis, with dense overlying pleural adhesions, but invasion of chest wall soft tissue by tumor is not identified. The overall features are consistent with squamous cell carcinoma, pT2N0.

GROSS DESCRIPTION

1. The specimen container is labeled with the patient's name and as "biopsy chest wall margin on silk stitch" contains a single piece of an irregular fragment of tan tissue received fresh. The tissue measures 3.8 x 1.5 x 2.5 cm. A suture is noted on the specimen. The margins are painted with silver nitrate, the site of suture is marked India ink. This is examined at intraoperative consultation by frozen section performed on part of the specimen. The specimen is submitted in toto as follows:

1A frozen section resubmitted (see diagram, en face) silver nitrate the margin India ink marks site of suture)

1B the rest of the specimen submitted in toto

2. The specimen container labeled with the patient's name and as "paraesophageal node", contains one of one of yellowish plaque tissue measuring 0.6 x 0.6 x 0.3 cm. received in 10% buffered formalin.

2A submitted in toto.

3. The specimen container labeled with the patient's name and as "inferior pulmonary ligament ST 9. ", contains one piece of yellowish black tissue measuring 0.6 x 0.4 x 0.3 cm. received in 10% buffered formalin.

3A submitted in toto.

4. The specimen container labeled with the patient's name and as

[page 4 of 6]
"interlobarST11", contains two pieces of tan black tissue measuring to 0.3 x 0.3 x 0.3 and 0.6 x 0.4 x 0.3 cm. received in 10% buffered formalin.

4A submitted in toto.

5. The specimen container is labeled with the patient's name and as "chest wall margin # 2. Query tumor Q. S." contains a single fragment of tan tissue received fresh. The tissue measures 0.3 x 0.2 x 0.2. This is examined at intraoperative consultation by frozen section performed on the entire specimen. The specimen is submitted in toto as follows:
5A frozen section resubmitted.

5. The specimen container labeled with the patient's name and as "right TB angle ST10R ", contains one piece of black-brown tissue measuring 0.9 x 0.6 x 0.6 cm. received in 10% buffered formalin.

6 A. specimen bisected and submitted in toto.

7. The specimen container is labeled with the patient's name and as "right upper lobe bronchial margin qs" contains a lobectomy specimen received in 10% buffered formalin. The specimen measures 14.3 x 8.5 x 8.0 cm. (The pleural surface overlying the tumor was painted with silver nitrate during tissue banking). On gross examination, there is a portion of parietal pleura adhered to the lung measuring 7.0 x 5.0 x 0.3 cm in thickness. The parietal pleura is yellow-tan and is firm and rubbery, with some areas that appears to be fatty. The rest of the pleura is tan in color and appears to be slightly thickened. On sectioning, there is a well-circumscribed tumor measuring 6.6 x 5.5 x 5.8 cm. The tumor abuts the pleura and has a variegated black tan appearance and is solid on the periphery and slightly soft and friable centrally. The tumor is 1.5 cm away from the nearest stapled resection margin.

The lung parenchyma adjacent to the tumor appears to be emphysematous and has a light yellow appearance. The rest of the lung parenchyma appears grossly unremarkable. One lobar lymph node is identified grossly within the hilar area measuring 1.5 x 1.5 x 0.8 cm.

Representative sections are submitted as follows:

7A frozen section resubmitted bronchial margin en face

7B-7D parietal pleura resection margin taken en face.

7E lung shave resection margin closest to tumor

7F-7J representative section of the tumor in relation to parietal pleura.

representative section of tumor in relation to parietal pleura and severely emphysematous lung parenchyma

[page 5 of 6]
Page: 5 of 6

[page 6 of 6]
[REDACTED]

11C two lymph nodes bisected.
11D one lymph node bisected.
11E one lymph node bisected.
11F one lymph node bisected.
11G one lymph node bisected.
11 H two lymph nodes

[REDACTED]

QUICK SECTION

1. Chest wall margin, area of stitch:
- En face margin negative for carcinoma
5. Chest wall margin #2:
- Negative for carcinoma
7. Bronchial resection margin negative for carcinoma
9. Negative for carcinoma
- [REDACTED]

Source: NCI Genomic Data Commons file d4930138-bda2-4c84-8a95-a07caf4cee70 (TCGA-18-3415.A37738C0-91CF-4E7E-B16C-3737A61BEA72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).